Somatic mutation profile of tumor specimen TCGA-PG-A916-01A (aliquot TCGA-PG-A916-01A-11D-A37N-09) from TCGA case TCGA-PG-A916, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.1 years (25,617 days).
Specimen TCGA-PG-A916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d0b6900-563d-476e-ac36-5524439c17a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PG-A916-10A (Blood Derived Normal), aliquot TCGA-PG-A916-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8f18534-2cc7-4fc0-88c0-6b65c6a5338e

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Frame Shift Del 7, Silent 6, RNA 1, Frame Shift Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>T p.D1810Y | Missense Mutation (SNP) | VAF 29/59 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.548dup p.N184Efs*6 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs1554900593, COSV64296770; ClinVar: pathogenic; called by mutect2, pindel
- ADPRHL1 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.087); catalogued as rs1211333124, COSV100733332; called by muse, mutect2, varscan2
- BSN | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs748615492, COSV99607085; called by muse, mutect2, varscan2
- CHDH | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.98); catalogued as COSV59458004; called by mutect2, varscan2
- CHST6 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs768271614, COSV100178265, COSV60001182; called by muse, mutect2, varscan2
- CLK2 | c.1095G>T p.W365C (on ENST00000368361 / NM_001294339.2; = p.W364C on NM_003993.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226574; called by muse, mutect2, varscan2
- DNAJB11 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.772); catalogued as rs1181730890, COSV54002248; called by muse, mutect2, varscan2
- GABRA6 | c.68T>A p.V23D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99194030; called by muse, mutect2, varscan2
- GATA4 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs745533633, COSV58732831; called by mutect2, varscan2
- HECW2 | c.3041T>G p.I1014S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99645621; called by muse, mutect2, varscan2
- KLK7 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100304351, COSV58343944; called by mutect2, varscan2
- LPCAT3 | c.893C>G p.T298R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.474); catalogued as COSV54641143, COSV99780928; called by muse, mutect2, varscan2
- NLRC5 | c.5101G>A p.G1701S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.45); catalogued as COSV99346334, COSV99347387; called by muse, mutect2, varscan2
- OR7G3 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100555590; called by muse, mutect2, varscan2
- PCDH9 | c.2908G>T p.D970Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100117900; called by muse, mutect2, varscan2
- PCDHGC5 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs1270788252, COSV52745850; called by muse, mutect2, varscan2
- PCK1 | c.1313C>G p.P438R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100099923, COSV60130391, COSV60131004; called by muse, mutect2, varscan2
- PTBP1 | c.51C>G p.D17E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV100608291, COSV100609351; called by muse, mutect2, varscan2
- PTEN | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as CM142080, COSV64289613, COSV64291984, COSV64295041; called by muse, mutect2, varscan2
- RBM41 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs775670658, COSV99179759; called by muse, varscan2
- RUNDC3A | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1480099674, COSV99841681; called by muse, varscan2
- TCEA1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67172521; called by muse, mutect2, varscan2
- THUMPD3 | c.134C>G p.P45R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100560494; called by muse, mutect2, varscan2
- TMPRSS15 | c.2611C>G p.R871G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV53047245, COSV99516679; called by muse, mutect2, varscan2
- TRANK1 | c.4358G>A p.C1453Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100081234; called by muse, mutect2, varscan2
- WDR75 | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100133983, COSV59106565; called by muse, mutect2, varscan2
- ZBED4 | c.2367G>C p.E789D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV99350722; called by muse, mutect2, varscan2
- ARF6 | c.522del p.K174Nfs*37 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP25 | c.1580_1581del p.S527* (on ENST00000409202 / NM_001007231.3; = p.S519* on NM_014882.3) | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- ARID1A | c.6253del p.L2085Wfs*50 | Frame Shift Del (DEL) | VAF 24/41 reads (59%) | called by mutect2, pindel, varscan2
- CTCF | c.1295_1301delinsGA p.E432Gfs*10 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by pindel, varscan2*
- RNF8 | c.756del p.M253Cfs*5 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- WDR82 | c.781_788del p.G261Pfs*17 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ZCWPW1 | c.1496del p.A499Efs*12 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- ACE | c.2898C>T p.N966= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs532039424, COSV52007198; called by muse, mutect2, varscan2
- DSCAM | c.4003C>A p.R1335= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs752819720, COSV101258904, COSV68020104; called by muse, varscan2
- EEF2 | c.579C>T p.G193= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100500537; called by muse, mutect2, varscan2
- PWWP3B | c.723A>G p.S241= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100530880; called by muse, mutect2, varscan2
- RAB3B | c.153C>T p.F51= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs764672569, COSV63228388; called by muse, mutect2, varscan2
- TCF4 | c.1056T>C p.P352= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1346152097; called by muse, mutect2
- AL136982.4 | n.433G>C | RNA (SNP) | VAF 73/182 reads (40%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457432 G>A | 5'Flank (SNP) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- THRA | c.1110+105T>C | Intron (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99225211; called by mutect2, varscan2
